Somatic mutation profile of tumor specimen TCGA-23-1123-01A (aliquot TCGA-23-1123-01A-01W-0488-09) from TCGA case TCGA-23-1123, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.0 years (21,552 days).
Specimen TCGA-23-1123-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4748f4a-9d7a-44a6-bf12-eda48a545dd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1123-10A (Blood Derived Normal), aliquot TCGA-23-1123-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9458c42b-657b-4b55-89ad-7ecc66a3cffe

The open-access MAF lists 88 somatic variants for this specimen: 73 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 13, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 2, Splice Region 1, Intron 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 62/83 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADNP | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 91/293 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs370301614; called by muse, mutect2, varscan2
- AKNA | c.677C>G p.P226R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV56312429, COSV56312684; called by muse, mutect2, varscan2
- ANKS6 | c.376G>C p.V126L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV62050335; called by muse, mutect2, varscan2
- AOC2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs142697203; called by muse, mutect2, varscan2
- ARHGAP35 | c.2255G>T p.S752I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV68331456; called by muse, mutect2, varscan2
- BCLAF1 | c.1353T>A p.D451E | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV62142277; called by muse, mutect2, varscan2
- BMPR2 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV65809538; called by muse, mutect2, varscan2
- CAMKV | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV56555431; called by muse, mutect2
- CAMTA1 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs77267405, COSV57902082; called by muse, mutect2, varscan2
- CCDC148 | c.1423G>T p.V475L | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV51760732; called by muse, mutect2, varscan2
- COL27A1 | c.5192G>T p.C1731F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61926273; called by muse, mutect2, varscan2
- CPB1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs766816862, COSV51573302; called by muse, mutect2, varscan2
- CPEB1 | c.509C>A p.P170H (on ENST00000617958; = p.P110H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55619003; called by muse, mutect2, varscan2
- CUX2 | c.3727G>C p.G1243R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV55632710; called by muse, mutect2, varscan2
- DGAT2L6 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV60717817; called by muse, mutect2, varscan2
- DPP10 | c.1074+1G>A p.X358_splice | Splice Site (SNP) | VAF 17/76 reads (22%) | catalogued as COSV59687573; called by muse, mutect2, varscan2
- DSG4 | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); catalogued as COSV100355164; called by muse, mutect2
- ENAM | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 132/336 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV101252877; called by muse, mutect2, varscan2
- EPS15L1 | c.2192G>C p.G731A | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV50168993; called by muse, mutect2, varscan2
- FAM171B | c.2285A>C p.H762P | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV59003718; called by muse, mutect2, varscan2
- FAM217A | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.215); catalogued as COSV51160203; called by muse, mutect2, varscan2
- FGD4 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV56783994; called by muse, mutect2, varscan2
- FH | c.1325C>G p.T442R | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1060500899, COSV63818212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIGNL1 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63553520; called by muse, mutect2, varscan2
- FMN2 | c.2425C>A p.Q809K | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV60418843, COSV60431060; called by muse, mutect2, varscan2
- GC | c.554T>C p.M185T | Missense Mutation (SNP) | VAF 67/598 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56737443; called by muse, mutect2, varscan2
- GNAS | c.489C>G p.Y163* | Nonsense Mutation (SNP) | VAF 14/133 reads (11%) | catalogued as CM002274, COSV55677028; called by muse, mutect2, varscan2
- HEPACAM2 | c.714T>A p.Y238* (on ENST00000394468 / NM_001039372.4; = p.Y226* on NM_198151.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/152 reads (28%) | catalogued as COSV59060502; called by muse, mutect2, varscan2
- IFFO1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59110677; called by muse, mutect2
- IFNA5 | c.329C>G p.T110S | Missense Mutation (SNP) | VAF 129/293 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as COSV52386873; called by muse, mutect2, varscan2
- KIF17 | c.2889C>A p.S963R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV56118302; called by muse, mutect2, varscan2
- LYST | c.3624G>T p.Q1208H | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV67707157; called by muse, mutect2, varscan2
- MAN2B1 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54418341; called by muse, mutect2, varscan2
- MMP13 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.049); catalogued as rs781966264, COSV52824119; called by muse, mutect2, varscan2
- MYO1F | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV57795300; called by muse, mutect2, varscan2
- NCF2 | c.448A>G p.M150V | Missense Mutation (SNP) | VAF 84/445 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs1340153036, COSV62315564; called by muse, mutect2, varscan2
- NUP160 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs772355663, COSV65854444; called by muse, mutect2, varscan2
- OR2AK2 | c.21T>A p.S7R | Missense Mutation (SNP) | VAF 132/576 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV63553053; called by muse, mutect2, varscan2
- OR5AK2 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 144/507 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV58804503; called by muse, mutect2, varscan2
- PABPC5 | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57040952; called by muse, mutect2, varscan2
- PASK | c.939A>C p.L313F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99299058; called by muse, mutect2, varscan2
- PLCB4 | c.1858A>G p.S620G | Missense Mutation (SNP) | VAF 39/913 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99593943; called by muse, mutect2
- PLCXD3 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 42/121 reads (35%) | catalogued as COSV60609020; called by muse, mutect2, varscan2
- PNISR | c.647del p.P216Lfs*2 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as COSV65079252; called by mutect2, pindel, varscan2
- PNP | c.602A>T p.E201V | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64091972; called by muse, mutect2, varscan2
- POTED | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as COSV55048268; called by muse, mutect2, varscan2
- PSMC4 | c.435dup p.E146Rfs*97 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs747871663; called by pindel, varscan2
- PTPRO | c.1654A>G p.R552G | Missense Mutation (SNP) | VAF 120/529 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV99839416; called by muse, mutect2, varscan2
- REP15 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs781501132, COSV57291892; called by muse, mutect2, varscan2
- RRH | c.955G>C p.V319L | Missense Mutation (SNP) | VAF 80/229 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV58491493, COSV58491931; called by muse, mutect2, varscan2
- SFXN1 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV58493426; called by muse, mutect2, varscan2
- SLC8A3 | c.2031G>T p.K677N (on ENST00000381269 / NM_183002.3; = p.K675N on NM_033262.4) | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53689717; called by muse, mutect2, varscan2
- SMARCA4 | c.2441C>A p.T814K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60792950, COSV60795041; called by muse, mutect2, varscan2
- SOX6 | c.1834C>T p.R612C (on ENST00000528429 / NM_001145819.2; = p.R585C on NM_017508.3) | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434670578, COSV57035391; called by muse, mutect2, varscan2
- THSD7B | c.1976C>A p.S659Y | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV55688410; called by muse, mutect2, varscan2
- TMEM248 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 191/428 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV100447449, COSV58577462; called by muse, mutect2, varscan2
- TRAPPC12 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201978278, COSV60847696; called by muse, mutect2, varscan2
- TRIM67 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs1424485115, COSV100792244, COSV64158114; called by muse, mutect2, varscan2
- TROAP | c.1718A>G p.E573G | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV57744230; called by muse, mutect2, varscan2
- TULP1 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV57692653; called by muse, mutect2, varscan2
- UBAP2L | c.1449G>C p.Q483H | Missense Mutation (SNP) | VAF 43/434 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as COSV55173039; called by muse, mutect2, varscan2
- UIMC1 | c.1676+1G>A p.X559_splice | Splice Site (SNP) | VAF 65/244 reads (27%) | catalogued as rs766653801, COSV65893601; called by muse, mutect2, varscan2
- VCAN | c.5395T>A p.L1799I | Missense Mutation (SNP) | VAF 65/114 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV54105510; called by muse, mutect2, varscan2
- ZC4H2 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as rs1490919537, COSV62003530, COSV62005568; called by muse, mutect2, varscan2
- ZMAT1 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 130/341 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV65658630; called by muse, mutect2, varscan2
- ZNF182 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 67/647 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1556898382, COSV59357357; called by muse, mutect2, varscan2
- ZNF285 | c.80A>G p.K27R | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.49); catalogued as COSV58409077; called by muse, mutect2, varscan2
- ZNF793 | c.862dup p.C288Lfs*28 | Frame Shift Ins (INS) | VAF 14/45 reads (31%) | catalogued as rs761241629; called by mutect2, varscan2
- ZNFX1 | c.3538A>G p.R1180G | Missense Mutation (SNP) | VAF 62/429 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV65597825; called by muse, mutect2, varscan2
- HLA-DOB | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 10/253 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- MDS2 | n.734C>A | Splice Region (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- SPIDR | c.438C>G p.D146E | Missense Mutation (SNP) | VAF 136/645 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ADGRE3 | c.783T>C p.D261= | Silent (SNP) | VAF 80/344 reads (23%) | catalogued as COSV53730731; called by muse, mutect2, varscan2
- AFP | c.765C>T p.I255= | Silent (SNP) | VAF 134/991 reads (14%) | catalogued as COSV56925306; called by muse, mutect2, varscan2
- AP3B2 | c.2727C>A p.I909= (on ENST00000261722; = p.I903= on NM_004644.5) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV55609808, COSV55612153; called by muse, mutect2, varscan2
- CRACR2A | c.708C>A p.L236= | Silent (SNP) | VAF 204/403 reads (51%) | catalogued as COSV52913089; called by muse, mutect2, varscan2
- JCAD | c.3303G>A p.P1101= | Silent (SNP) | VAF 80/341 reads (23%) | catalogued as rs1311204726, COSV64759711; called by muse, mutect2, varscan2
- P4HA1 | c.729T>A p.G243= | Silent (SNP) | VAF 48/269 reads (18%) | catalogued as COSV54961644; called by muse, mutect2, varscan2
- PKP4 | c.1008G>A p.S336= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as rs200934987, COSV67677182; called by muse, mutect2, varscan2
- PPFIBP2 | c.1347C>T p.D449= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as rs765647290, COSV55077230; called by muse, mutect2, varscan2
- QRICH1 | c.2094A>G p.P698= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV58707960; called by muse, mutect2, varscan2
- SNX8 | c.708C>A p.R236= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV56127011, COSV56127447, COSV99771232; called by muse, mutect2, varscan2
- SPATA31E1 | c.3621C>T p.H1207= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1428646208, COSV57791597; called by muse, mutect2
- STARD5 | c.534C>A p.T178= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV100250949, COSV57154928; called by muse, mutect2, varscan2
- XPO1 | c.763C>T p.L255= | Silent (SNP) | VAF 36/179 reads (20%) | catalogued as COSV101294187, COSV68946036; called by muse, mutect2, varscan2
- LMNA | c.357-3720C>T | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs760318158, COSV61543001; called by mutect2, varscan2
- VAX1 | chr10:117132237 G>T | 3'Flank (SNP) | VAF 4/10 reads (40%) | catalogued as COSV53328674, COSV53329131; called by muse, mutect2
